Somatic mutation profile of tumor specimen C3N-00689-54 (aliquot CPT0438250002) from CPTAC case C3N-00689, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 51.9 years (18,949 days).
Specimen C3N-00689-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35ed621f-7dbc-49ae-ab5b-eb89a67638c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00689-50 (Buccal Cell Normal), aliquot CPT0435150001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7804a5f5-11a6-415e-9122-410025ad9922

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Ins 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 125/287 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRRC37B | c.2226dup p.N743* | Frame Shift Ins (INS) | VAF 62/392 reads (16%) | called by mutect2, varscan2
- RAD51AP1 | c.517G>T p.A173S (on ENST00000228843 / NM_001130862.2; = p.A156S on NM_006479.5) | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- UNC5C | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 65/165 reads (39%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210162879 C>A | 3'Flank (SNP) | VAF 30/99 reads (30%) | catalogued as rs986824191; called by muse, mutect2, varscan2
